HCMI case HCM-CSHL-0065-C20 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b5fe3fa5-0f46-4e63-8e1f-dc3d28734936

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1954; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 63.3 years (23,111 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IVA; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Liver.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: Yes; Vascular invasion type: Extramural.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 48 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 18 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 18 days.
- Days to follow up: 442 days (1.2 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 186.

Molecular and laboratory tests
- CEA: 77.
- MLH1 (IHC): Negative.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 61.2 kg; Height: 162.5 cm; BMI: 23.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Days to comorbidity: 48 days; Days to risk factor: 48 days; Risk factors: Colon Polyps.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0065-C20-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0065-C20-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 19; Percent stromal cells: 41; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0065-C20-06A-01-S1-HE: Section location: Top; Percent tumor cells: 36; Percent tumor nuclei: 73; Percent normal cells: 12; Percent necrosis: 18; Percent stromal cells: 34; Percent lymphocyte infiltration: 16; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0065-C20-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0065-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
